Somatic mutation profile of tumor specimen C3N-00310-03 (aliquot CPT0009000006) from CPTAC case C3N-00310, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 84.9 years (31,016 days).
Specimen C3N-00310-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e74309e7-6665-4636-b1c6-01161ea44a8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00310-31 (Blood Derived Normal), aliquot CPT0009030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eb34d25-0dc8-4938-b6ff-5477220fb226

The open-access MAF lists 152 somatic variants for this specimen: 100 protein-altering or splice-affecting, 33 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 33, Intron 14, Frame Shift Del 10, Splice Site 5, Nonsense Mutation 2, In Frame Del 2, Splice Region 2, 3'UTR 2, Frame Shift Ins 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 67/182 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.340+2T>A p.X114_splice | Splice Site (SNP) | VAF 114/205 reads (56%) | hotspot (GDC flag); catalogued as CD983001, COSV56547957, COSV56551654, COSV56551713, COSV56563827; called by muse, mutect2, varscan2
- BACH1 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV54521242; called by muse, mutect2, varscan2
- CCDC65 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.87); catalogued as rs376799979; called by muse, mutect2, varscan2
- CENPJ | c.4000A>G p.M1334V | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs774140825; called by muse, mutect2, varscan2
- CLDN16 | c.615del p.A206Pfs*26 | Frame Shift Del (DEL) | VAF 114/407 reads (28%) | catalogued as CM060926; called by mutect2, pindel, varscan2
- COLEC12 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs765394463, COSV68374660; called by muse, mutect2, varscan2
- CSMD3 | c.3395C>A p.P1132Q (on ENST00000297405 / NM_001363185.1; = p.P1028Q on NM_052900.3) | Missense Mutation (SNP) | VAF 128/394 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765683126; called by muse, mutect2, varscan2
- DGKZ | c.2057C>G p.S686C (on ENST00000454345 / NM_001105540.2; = p.S498C on NM_003646.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV58988293; called by muse, mutect2, varscan2
- DOCK5 | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52395508, COSV52404091; called by muse, mutect2, varscan2
- DOK4 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1422790855, COSV99538313; called by muse, mutect2, varscan2
- FKBP9 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); catalogued as rs796764966; called by muse, mutect2, varscan2
- HCN4 | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs373284500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGSF1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); catalogued as rs750533250, COSV63839200; called by muse, mutect2, varscan2
- LRBA | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 79/323 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs945099173; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAPKBP1 | c.3070C>T p.L1024F (on ENST00000456763 / NM_001128608.2; = p.L1018F on NM_014994.3) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1463119166; called by muse, mutect2, varscan2
- MATN4 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 43/157 reads (27%) | PolyPhen probably damaging (1); catalogued as COSV59213028; called by muse, mutect2, varscan2
- MUC2 | c.2942C>T p.A981V | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs766848359; called by muse, mutect2, varscan2
- NOX4 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1358349700; called by muse, mutect2, varscan2
- PIAS4 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs368054611, COSV53681082; called by muse, mutect2, varscan2
- PRKCQ | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756942026, COSV54119832; called by muse, mutect2, varscan2
- PSMC6 | c.65C>T p.A22V (on ENST00000612399; = p.A8V on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/344 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs771076814; called by muse, mutect2, varscan2
- SLC9C2 | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs764739922; called by muse, mutect2, varscan2
- SMARCA4 | c.3304T>C p.F1102L | Missense Mutation (SNP) | VAF 187/617 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60790620; called by muse, mutect2, varscan2
- STPG3 | c.108C>G p.T36= | Splice Region (SNP) | VAF 41/119 reads (34%) | catalogued as COSV100547010; called by muse, mutect2, varscan2
- TLK1 | c.587T>G p.F196C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.784); catalogued as rs1021006550; called by muse, mutect2, varscan2
- ZFAND4 | c.1823A>T p.E608V | Missense Mutation (SNP) | VAF 86/239 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs762806906; called by muse, mutect2, varscan2
- ACSL5 | c.1214T>A p.I405N (on ENST00000354273; = p.I461N on NM_016234.3) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- AGAP6 | c.1669C>G p.L557V (on ENST00000374056 / NM_001365867.1; = p.L580V on NM_001077665.2) | Missense Mutation (SNP) | VAF 181/807 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AHCTF1 | c.2345C>T p.T782I (on ENST00000366508; = p.T756I on NM_015446.5) | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANKRD26 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 116/341 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF17 | c.5546T>A p.L1849Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF3 | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ATP1B1 | c.376dup p.C126Lfs*7 | Frame Shift Ins (INS) | VAF 32/101 reads (32%) | called by mutect2, pindel, varscan2
- CACNA1C | c.3474G>T p.M1158I | Missense Mutation (SNP) | VAF 75/275 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CAGE1 | c.893C>T p.P298L (on ENST00000512086; = p.P162L on NM_205864.3) | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CBFA2T3 | c.1364C>A p.P455H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDK17 | c.397_400del p.H133Dfs*8 | Frame Shift Del (DEL) | VAF 39/160 reads (24%) | called by mutect2, pindel, varscan2
- CENPJ | c.2692+1G>C p.X898_splice | Splice Site (SNP) | VAF 42/142 reads (30%) | called by muse, mutect2, varscan2
- CFAP221 | c.196_201del p.H66_F67del | In Frame Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- CLCN5 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 121/171 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CNPY3 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CPAMD8 | c.5272G>A p.G1758S (on ENST00000651564; = p.G1711S on NM_015692.5) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated, low confidence (0.76); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- DGLUCY | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 88/250 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DGUOK | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 179/500 reads (36%) | called by muse, mutect2, varscan2
- DIAPH1 | c.2473+1G>A p.X825_splice | Splice Site (SNP) | VAF 174/608 reads (29%) | called by muse, mutect2, varscan2
- DPYSL5 | c.29T>A p.I10N | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- EIPR1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM200A | c.1558T>C p.F520L | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCGBP | c.4149C>G p.Y1383* | Nonsense Mutation (SNP) | VAF 216/876 reads (25%) | called by muse, varscan2
- FTSJ3 | c.1819C>A p.L607I | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GABRA4 | c.1331C>G p.T444S | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GALNT7 | c.1817A>C p.K606T | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GARNL3 | c.2709A>C p.K903N | Missense Mutation (SNP) | VAF 104/363 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GIMAP6 | c.798del p.E266Dfs*122 | Frame Shift Del (DEL) | VAF 121/342 reads (35%) | called by mutect2, pindel, varscan2
- HEATR5B | c.2833G>A p.D945N | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HFM1 | c.1898T>C p.M633T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- HJURP | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 13/340 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.396); called by muse, mutect2
- HOXA2 | c.14T>A p.F5Y | Missense Mutation (SNP) | VAF 99/307 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HOXA4 | c.79A>T p.S27C | Missense Mutation (SNP) | VAF 135/438 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- HSFX4 | c.397A>C p.N133H | Missense Mutation (SNP) | VAF 100/135 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- KDM5C | c.2885del p.P962Lfs*16 | Frame Shift Del (DEL) | VAF 88/165 reads (53%) | called by mutect2, pindel, varscan2
- KDR | c.3838_3848+3del p.X1280_splice | Splice Site (DEL) | VAF 52/252 reads (21%) | called by mutect2, pindel
- KIRREL3 | c.349del p.A117Qfs*41 | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | called by mutect2, pindel, varscan2
- MAP3K5 | c.526A>T p.S176C | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MRPL44 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, varscan2
- NBN | c.221A>C p.Y74S | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NES | c.3646C>A p.P1216T | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP98 | c.4075G>A p.A1359T (on ENST00000359171 / NM_001365126.1; = p.A1342T on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- OR1A2 | c.797G>T p.S266I | Missense Mutation (SNP) | VAF 87/417 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- OR5AN1 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PBRM1 | c.2225_2226del p.E742Vfs*16 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- PCDH8 | c.2467A>C p.T823P | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PHTF1 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, varscan2
- PIGN | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PITPNM2 | c.2946del p.S983Qfs*14 | Frame Shift Del (DEL) | VAF 74/222 reads (33%) | called by mutect2, pindel, varscan2
- PLA2G4D | c.488G>A p.C163Y | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PLXND1 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PXMP4 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- R3HCC1L | c.2074+1del | Frame Shift Del (DEL) | VAF 45/135 reads (33%) | called by mutect2, pindel, varscan2
- RADX | c.845_850del p.L282_C283del | In Frame Del (DEL) | VAF 48/75 reads (64%) | called by mutect2, pindel, varscan2
- RALYL | c.190A>C p.S64R | Missense Mutation (SNP) | VAF 83/273 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- RANBP17 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RGL1 | c.2221A>G p.K741E (on ENST00000360851 / NM_001297672.2; = p.K776E on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RNF128 | c.1150A>C p.T384P (on ENST00000255499 / NM_194463.2; = p.T358P on NM_024539.3) | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RNF20 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCEL | c.1218T>A p.G406= (on ENST00000349847 / NM_144777.3; = p.G386= on NM_003843.4) | Splice Region (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- SEC31A | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- SLC39A13 | c.729_731dup p.S243_K244insN | In Frame Ins (INS) | VAF 159/509 reads (31%) | called by mutect2, pindel, varscan2
- SLCO2A1 | c.1026T>G p.I342M | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA2L | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPDL1 | c.82T>A p.L28I | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPTBN1 | c.567-1G>T p.X189_splice | Splice Site (SNP) | VAF 71/203 reads (35%) | called by muse, mutect2, varscan2
- TBX19 | c.1157C>A p.P386Q | Missense Mutation (SNP) | VAF 181/556 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TG | c.5728del p.T1910Qfs*32 | Frame Shift Del (DEL) | VAF 121/421 reads (29%) | called by mutect2, pindel, varscan2
- TSNAXIP1 | c.426del p.K142Nfs*12 | Frame Shift Del (DEL) | VAF 46/205 reads (22%) | called by mutect2, pindel, varscan2
- TTN | c.48170G>A p.G16057D (on ENST00000591111; = p.G8633D on NM_003319.4) | Missense Mutation (SNP) | VAF 201/601 reads (33%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE2V2 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZNF207 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 95/351 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); called by muse, varscan2
- ZNF792 | c.1610G>A p.S537N | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AATK | c.138C>T p.I46= | Silent (SNP) | VAF 78/274 reads (28%) | catalogued as rs746392822; called by muse, mutect2, varscan2
- ACSL5 | c.1215C>T p.I405= (on ENST00000354273; = p.I461= on NM_016234.3) | Silent (SNP) | VAF 30/106 reads (28%) | called by mutect2, varscan2
- ADGRG1 | c.276C>G p.L92= | Silent (SNP) | VAF 225/783 reads (29%) | called by muse, mutect2, varscan2
- ATP10A | c.1746C>T p.V582= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs369407036; called by mutect2, varscan2
- ATP8B2 | c.627A>G p.V209= (on ENST00000672630; = p.V176= on NM_001005855.2) | Silent (SNP) | VAF 57/172 reads (33%) | called by muse, mutect2, varscan2
- AVEN | c.544T>C p.L182= | Silent (SNP) | VAF 79/254 reads (31%) | called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.909T>A p.I303= | Silent (SNP) | VAF 74/251 reads (29%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.369A>G p.L123= | Silent (SNP) | VAF 87/229 reads (38%) | called by muse, mutect2, varscan2
- FCN3 | c.336T>C p.P112= | Silent (SNP) | VAF 53/162 reads (33%) | called by muse, mutect2, varscan2
- FOXK2 | c.1248C>T p.I416= | Silent (SNP) | VAF 52/134 reads (39%) | catalogued as COSV100081950; called by muse, mutect2, varscan2
- IGFBP7 | c.135G>A p.P45= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs11555292; called by muse, mutect2, varscan2
- IL4R | c.534C>T p.T178= | Silent (SNP) | VAF 62/205 reads (30%) | called by muse, mutect2, varscan2
- INSR | c.2775C>T p.I925= | Silent (SNP) | VAF 163/494 reads (33%) | called by muse, mutect2, varscan2
- KDR | c.1563G>A p.A521= | Silent (SNP) | VAF 183/595 reads (31%) | catalogued as rs200769864, COSV55771803; called by muse, mutect2, varscan2
- KIF14 | c.1116G>A p.E372= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as rs1460233741; called by muse, mutect2
- KRT7 | c.132C>T p.A44= | Silent (SNP) | VAF 55/171 reads (32%) | called by muse, mutect2, varscan2
- MS4A4A | c.375T>C p.T125= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- NDUFS2 | c.456T>C p.S152= | Silent (SNP) | VAF 198/705 reads (28%) | called by muse, mutect2, varscan2
- NUP98 | c.3141G>A p.G1047= (on ENST00000359171 / NM_001365126.1; = p.G1030= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2, varscan2
- OPRD1 | c.510C>T p.I170= | Silent (SNP) | VAF 68/205 reads (33%) | called by muse, mutect2, varscan2
- PILRA | c.282G>A p.V94= | Silent (SNP) | VAF 124/512 reads (24%) | catalogued as COSV104388762; called by muse, varscan2
- PKHD1 | c.7953A>C p.L2651= | Silent (SNP) | VAF 117/294 reads (40%) | called by muse, mutect2, varscan2
- POMT1 | c.714C>T p.V238= | Silent (SNP) | VAF 165/578 reads (29%) | called by muse, mutect2, varscan2
- RHBDF1 | c.33C>T p.S11= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs909695870; called by muse, varscan2
- RUSC1 | c.999G>T p.P333= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs751785225; called by muse, mutect2, varscan2
- SLC26A2 | c.765A>C p.G255= | Silent (SNP) | VAF 95/260 reads (37%) | called by muse, mutect2, varscan2
- SPNS1 | c.726A>C p.P242= | Silent (SNP) | VAF 82/304 reads (27%) | called by muse, mutect2, varscan2
- SRSF10 | c.192T>G p.A64= | Silent (SNP) | VAF 86/250 reads (34%) | catalogued as COSV100086941; called by muse, mutect2, varscan2
- TBXT | c.810C>T p.L270= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- TOGARAM1 | c.1239C>A p.G413= | Silent (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- UMOD | c.417G>C p.A139= | Silent (SNP) | VAF 88/272 reads (32%) | called by muse, mutect2, varscan2
- ZBED6 | c.558G>A p.R186= | Silent (SNP) | VAF 62/187 reads (33%) | catalogued as rs1401224748; called by muse, mutect2, varscan2
- ZC3H12C | c.1062T>C p.D354= | Silent (SNP) | VAF 166/438 reads (38%) | called by muse, mutect2, varscan2
- ABCA13 | c.12070+74T>G | Intron (SNP) | VAF 57/167 reads (34%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9071C>T | Intron (SNP) | VAF 286/967 reads (30%) | catalogued as COSV101595564; called by muse, mutect2, varscan2
- BRINP2 | c.461-66T>C | Intron (SNP) | VAF 82/251 reads (33%) | called by muse, mutect2, varscan2
- C7orf50 | c.130-18160G>A | Intron (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2
- FMR1 | c.*481G>C | 3'UTR (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- GALNT3 | c.1191+31A>T | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- HLX | c.957+20A>C | Intron (SNP) | VAF 53/141 reads (38%) | called by muse, mutect2, varscan2
- IGSF22 | c.*63del | 3'UTR (DEL) | VAF 93/365 reads (25%) | called by mutect2, pindel, varscan2
- KAZALD1 | chr10:101067948 C>T | 3'Flank (SNP) | VAF 54/170 reads (32%) | called by muse, mutect2, varscan2
- LIMCH1 | c.2243-786C>T | Intron (SNP) | VAF 77/245 reads (31%) | catalogued as rs757602137, COSV58285020; called by muse, mutect2, varscan2
- MUC19 | n.5319G>C | RNA (SNP) | VAF 62/170 reads (36%) | called by muse, mutect2, varscan2
- NEB | c.11601+6152G>A | Intron (SNP) | VAF 102/668 reads (15%) | catalogued as rs772352938; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NT5C2 | c.687+9T>C | Intron (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- PHC3 | c.144+1904T>C | Intron (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- PIK3CD | c.-138+2446G>A | Intron (SNP) | VAF 225/691 reads (33%) | called by muse, mutect2, varscan2
- PRM1 | c.-26C>A | 5'UTR (SNP) | VAF 118/399 reads (30%) | called by muse, mutect2, varscan2
- ROBO3 | c.2846+22C>T | Intron (SNP) | VAF 75/247 reads (30%) | called by muse, mutect2, varscan2
- TNS1 | c.2632+5351G>C | Intron (SNP) | VAF 52/143 reads (36%) | called by muse, mutect2, varscan2
- WDR38 | c.308-10G>C | Intron (SNP) | VAF 97/319 reads (30%) | called by muse, mutect2, varscan2
